Gene-level copy-number profile of tumor specimen ALCH-B3D2-TTP1-A from ALCHEMIST case ALCH-B3D2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.7 years (27,665 days).
Specimen ALCH-B3D2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 940f4604-f4bf-4310-bd9e-911b6fc8c25a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3D2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/4d921552-8f58-4249-a16e-5be51f96337b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 502; copy number 1: 12,742; copy number 2: 38,666; copy number 3: 5,239; copy number 4: 705; copy number 5: 65; copy number 6: 953; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,303,304–4,847,840, 4 genes (within-gene range 0–1): SETMAR, MRPS10P2, ITPR1-DT, ITPR1.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr9:21,209,189–23,849,914, 53 genes (within-gene range 0–1): IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1.
- chr9:39,191,100–39,191,360, 1 gene (within-gene range 0–1): RN7SL640P.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr11:127,204–139,612, 1 gene (within-gene range 0–3): LINC01001.
- chr20:62,302,093–62,308,862, 2 genes (within-gene range 0–1): ADRM1, AL354836.1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–1): MIR4758.
- chr21:44,172,169–44,194,338, 2 genes: AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,020 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,944,428–198,123,232, 954 genes, copy number 6–9 (broad region; genes not listed).
- chr4:73,052,362–75,990,962, 62 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.
- chr21:29,055,805–29,073,797, 1 gene, copy number 5 (within-gene range 1–5): CCT8.
- chr21:29,063,446–29,064,368, 1 gene, copy number 5: AF129075.3.
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 0–9): GATD3A.

Autosomal genes at a single copy (total copy number 1): 10,387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
